Somatic mutation profile of tumor specimen MP2PRT-PAUPSD-TMP1-A (aliquot MP2PRT-PAUPSD-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUPSD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,513 days).
Specimen MP2PRT-PAUPSD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8cfc761-fb36-409d-8937-79bd001fa7c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPSD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPSD-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c592a6e2-b796-4395-b69b-5c737297c545

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF28 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 37/466 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs376370183; called by muse, mutect2
- IGFN1 | c.2411C>T p.T804M (on ENST00000295591 / NM_001367841.1; = p.T3261M on NM_001164586.2) | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs755243413, COSV99813891; called by muse, mutect2, varscan2
- KCNT2 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs775890073; called by muse, mutect2, varscan2
- MRC2 | c.4315C>T p.R1439C | Missense Mutation (SNP) | VAF 169/365 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776632141; called by muse, mutect2, varscan2
- PPP1R9A | c.3108G>C p.Q1036H | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as COSV56898641; called by muse, mutect2
- PRELP | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as rs200674304, COSV58115153; called by muse, mutect2, varscan2
- SLCO2A1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 147/305 reads (48%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as rs532222872; called by muse, mutect2, varscan2
- XRCC1 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 22/466 reads (5%) | catalogued as rs200894967; called by muse, mutect2
- SMU1 | c.1150_1151insGCTCCC p.S384delinsCSP | In Frame Ins (INS) | VAF 75/196 reads (38%) | called by mutect2, pindel, varscan2
- XIRP1 | c.3913G>A p.G1305R | Missense Mutation (SNP) | VAF 177/355 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP4A | c.372C>T p.I124= | Silent (SNP) | VAF 171/334 reads (51%) | catalogued as rs371245307; called by muse, mutect2, varscan2
- TAF3 | c.996A>G p.Q332= | Silent (SNP) | VAF 179/371 reads (48%) | called by muse, mutect2, varscan2
- VLDLR | c.2292G>A p.T764= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs753958817, COSV66077593; called by muse, mutect2
